TCGA case TCGA-BA-6870 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Larynx; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/730c3b27-24d5-4a80-b659-db54cd2bc4fa

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Dead; Days to death: 451 days (1.2 years).

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C32.9; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 60.8 years (22,222 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N2c; AJCC clinical M: M1; AJCC clinical stage: Stage IVC; AJCC pathologic T: TX; AJCC pathologic N: NX; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 60 days; Days to treatment end: 152 days.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 76 days; Days to treatment end: 144 days; Treatment dose: 6,996 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 451.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 40; Tobacco smoking onset year: 1970.
- Alcohol history: Yes; Alcohol days per week: 5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BA-6870-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.6; Shortest dimension: 0.5.
  Slide TCGA-BA-6870-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 3; Percent neutrophil infiltration: 1.
  Slide TCGA-BA-6870-01A-01-TS1: Section location: Top; Percent tumor cells: 97; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 2; Percent neutrophil infiltration: 1.
- Sample TCGA-BA-6870-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BA-6870-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Lymph nodes examined: No; Lymph node neck dissection indicator: No; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 5.
- Drug treatment: Regimen number: 1.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Pt with synchronous malignancy of bilateral lung cancers.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 451 days; disease-specific survival: event status not recorded, 451 days; progression-free interval: no event (censored), 451 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BA-6870-01A-11D-1869-01): tumor purity 0.32, ploidy 3.64, whole-genome doublings 1.
